CCDI case PBCHSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e2ff2735-8d76-478e-982d-6f5cdd650333

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,157 days).

Biospecimens (3 samples)
- Sample 0DS52I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS532: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS544: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
